CCDI case PBCALJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/499feb07-c075-4172-b112-a81ea1be7c50

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neuroepithelioma, NOS: ICD-O-3 morphology code: 9503/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 11.4 years (4,170 days).

Biospecimens (3 samples)
- Sample 0DMKKL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKKW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMKL2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
